TCGA case TCGA-XK-AAIV — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: Mayo Clinic Arizona. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0e747c7e-3621-4d88-847c-86811655d908

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 63.9 years (23,325 days); Year of diagnosis: 2011; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N1; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 10.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 18; Tumor level prostate: Apex / Middle / Base.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Bicalutamide; Days to treatment start: 97 days; Days to treatment end: 126 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 111 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 170 days; Days to treatment end: 232 days; Treatment dose: 7,000 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.

Follow-up (5 entries)
- Day 16 (initial diagnosis): Days to imaging: 16 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 20 (initial diagnosis): Days to imaging: 20 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 42 (initial diagnosis): Days to imaging: 42 days; Imaging type: MRI; Imaging findings: Extraprostatic Extension, Localized.
- Days to follow up: 958 days (2.6 years); Disease response: With Tumor.
- Days to follow up: 1,133 days (3.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.32 ng/mL (day 85).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XK-AAIV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-XK-AAIV-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-XK-AAIV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XK-AAIV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Diagnostic mri results: Mri results: Extraprostatic Extension Localized (e.g. seminal vesicles).
- Stage record, Psa: PSA most recent results: 0.32.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 5.
- Drug treatment 1: Pharmaceutical therapy drug name: Lupron.
- Drug treatment 2: Pharmaceutical therapy drug name: Casodex.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,133 days; disease-specific survival: no event (censored), 1,133 days; disease-free interval: no event (censored), 1,133 days; progression-free interval: no event (censored), 1,133 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XK-AAIV-01A-11D-A41J-01): tumor purity 0.24, ploidy 3.51, whole-genome doublings 1.
